Gene-level copy-number profile of tumor specimen BLGSP-71-22-00339-01A from CGCI case BLGSP-71-22-00339, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 8.3 years (3,038 days).
Specimen BLGSP-71-22-00339-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Omentum; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1f88ca62-ecac-48d7-9d42-c43c8bf7bae6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-22-00339-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: a second AscatNGS file.
https://portal.gdc.cancer.gov/files/b5047e35-b5b1-4857-b042-62570cb65a21

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 283; copy number 1: 8,658; copy number 2: 46,619; copy number 3: 2,347; copy number 4: 949; copy number 5: 10; copy number 6: 29; copy number 8: 1; copy number 19: 2; copy number 20: 1.

Homozygous deletions (total copy number 0; autosomes only): 272 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,892,896–12,922,660, 3 genes (within-gene range 0–2): PRAMEF10, PRAMEF7, RNU6-1072P.
- chr1:12,938,472–13,032,130, 2 genes (within-gene range 0–2): PRAMEF6, PRAMEF28P.
- chr1:13,060,869–13,062,229, 1 gene (within-gene range 0–1): HNRNPCL3.
- chr1:13,222,705–13,285,174, 6 genes: PRAMEF18, PRAMEF31P, PRAMEF5, PRAMEF32P, RNU6-771P, PRAMEF8.
- chr1:243,029,512–243,101,744, 5 genes: SEPTIN14P21, CICP21, AL606534.4, LINC01347, RNU6-747P.
- chr2:88,811,186–89,245,596, 40 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr2:90,190,193–91,621,421, 11 genes (within-gene range 0–1): IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1.
- chr2:91,686,102–91,781,169, 6 genes: AC027612.2, NKAIN1P2, AC027612.1, KMT5AP2, AC027612.3, GGT8P.
- chr3:109,293,788–109,337,572, 3 genes: DPPA2, Metazoa_SRP, DPPA4.
- chr7:140,404,058–140,479,536, 3 genes (within-gene range 0–1): RAB19, AC069335.1, MKRN1.
- chr7:152,445,477–152,593,091, 4 genes: CCT8L1P, LINC01003, AC104843.2, 5S_rRNA.
- chr8:69,987,415–70,078,032, 3 genes: SUMO2P20, PRDM14, RNU1-101P.
- chr10:34,815,767–34,816,386, 1 gene: PARD3-AS1.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr12:101,424,441–101,486,997, 5 genes: RPS27P23, Y_RNA, RNU5E-5P, RNA5SP367, SPIC.
- chr12:114,682,292–114,771,851, 4 genes (within-gene range 0–2): AC026765.3, AC026765.4, AC026765.1, AC026765.2.
- chr14:105,672,308–106,631,653, 151 genes (within-gene range 0–3) (broad region; genes not listed).
- chr14:106,637,718–106,639,657, 2 genes (within-gene range 0–3): IGHVII-60-1, IGHV4-61.
- chr14:106,657,725–106,672,073, 3 genes (within-gene range 0–3): IGHV3-64, IGHV3-65, IGHVII-65-1.
- chr17:62,036,833–62,140,639, 3 genes (within-gene range 0–1): Y_RNA, Y_RNA, POLRMTP1.
- chr19:32,978,592–33,130,542, 4 genes: RHPN2, AC008521.1, AC008521.2, GPATCH1.
- chr22:22,822,658–22,886,379, 11 genes (within-gene range 0–1): IGLV2-8, MIR650, AC245028.2, IGLV3-7, IGLV3-6, IGLV2-5, IGLV3-4, IGLV4-3, IGLV3-2, IGLV3-1, MIR5571.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 43 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,172,455–13,179,464, 1 gene, copy number 20: PRAMEF9.
- chr3:152,118,173–152,151,724, 1 gene, copy number 6: AC108718.1.
- chr3:186,930,325–188,890,671, 26 genes, copy number 6: ST6GAL1, RPL39L, AC007920.1, RTP1, MASP1, AC007920.2, RTP4, AC068299.2, AC068299.1, LINC02041, SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28.
- chr15:21,298,233–21,325,241, 2 genes, copy number 19: AC068446.2, RNU6-1235P.
- chr15:22,125,511–22,126,434, 1 gene, copy number 8 (within-gene range 4–8): OR4N3P.
- chr15:22,178,107–22,185,402, 2 genes, copy number 5: IGHV1OR15-3, IGHV4OR15-8.
- chr16:85,924,984–85,948,824, 2 genes, copy number 6: AC092723.5, LINC02132.
- chr22:22,910,574–22,923,034, 8 genes, copy number 5: IGLJ4, IGLC4, IGLJ5, IGLC5, IGLJ6, IGLC6, IGLJ7, IGLC7.

Autosomal genes at a single copy (total copy number 1): 6,385. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
